Somatic mutation profile of tumor specimen TCGA-HT-8010-01A (aliquot TCGA-HT-8010-01A-11D-2395-08) from TCGA case TCGA-HT-8010, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 64.8 years (23,680 days).
Specimen TCGA-HT-8010-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9c6c3a5-17f6-4781-8db5-16824ba3ee1a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-8010-10A (Blood Derived Normal), aliquot TCGA-HT-8010-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b98fb2e8-054b-4919-a4ba-07d28cbd3c63

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 8, Silent 4, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 25/87 reads (29%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- CCDC88A | c.676C>T p.H226Y | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.075); catalogued as COSV55059148; called by muse, mutect2, varscan2
- DST | c.14257A>G p.S4753G (on ENST00000361203 / NM_001374722.1; = p.S2341G on NM_015548.5) | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV55006073; called by muse, mutect2
- ITGAL | c.1082G>A p.G361D | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV63321164; called by muse, mutect2, varscan2
- JADE3 | c.361A>G p.T121A | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV54465365; called by muse, mutect2, varscan2
- NF1 | c.2983del p.L995Wfs*17 | Frame Shift Del (DEL) | VAF 38/159 reads (24%) | catalogued as COSV100646606; called by mutect2, pindel, varscan2
- POFUT2 | c.1142T>G p.F381C | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57958479; called by muse, mutect2, varscan2
- USP11 | c.1598C>T p.T533M (on ENST00000218348; = p.T490M on NM_001371072.1) | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.845); catalogued as rs761179924, COSV54473055; called by muse, mutect2, varscan2
- ZNF182 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.609); catalogued as COSV59356592; called by muse, mutect2, varscan2
- CIC | c.3138_3144delinsCCGCT p.P1047Rfs*103 | Frame Shift Del (DEL) | VAF 5/46 reads (11%) | called by pindel, varscan2*
- AOC1 | c.1455C>T p.V485= | Silent (SNP) | VAF 23/112 reads (21%) | catalogued as rs1034043121, COSV62867737; called by muse, mutect2, varscan2
- ATP11C | c.519C>G p.T173= | Silent (SNP) | VAF 80/281 reads (28%) | catalogued as COSV59561340; called by muse, mutect2, varscan2
- MFNG | c.64C>T p.L22= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs778930375, COSV52655299, COSV99052991; called by muse, mutect2, varscan2
- TMEM68 | c.573C>T p.H191= | Silent (SNP) | VAF 21/109 reads (19%) | catalogued as COSV58170363; called by muse, mutect2, varscan2
